Somatic mutation profile of tumor specimen HTMCP-03-06-02067-01A (aliquot HTMCP-03-06-02067-01A-01D-4427) from CGCI case HTMCP-03-06-02067, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G3; Age at diagnosis: 29.6 years (10,814 days).
Specimen HTMCP-03-06-02067-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a98b3336-10d9-4262-a05c-f593526ea653.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02067-10A (Blood Derived Normal), aliquot HTMCP-03-06-02067-10A-01D-4427; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89e0549a-b811-434b-8972-2490553c8766

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLG2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 28/295 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as COSV66166901; called by muse, mutect2
- HDAC6 | c.3410G>A p.G1137E | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs373313895; called by muse, mutect2, varscan2
- ADAMTS1 | c.2429G>A p.R810K | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.27); called by muse, mutect2
- BAZ2A | c.5147G>A p.G1716E | Missense Mutation (SNP) | VAF 23/281 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC88A | c.3851G>A p.R1284K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CTNND2 | c.2514C>G p.I838M | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.541); called by muse, mutect2
- DLGAP5 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- DNAH9 | c.11692C>T p.P3898S | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- KIF13B | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2
- USP15 | c.1558-1G>C p.X520_splice (on ENST00000280377 / NM_001351159.2; = p.X491_splice on NM_006313.3 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- USP32 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.405); called by muse, mutect2
- ZNF347 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.087); called by muse, mutect2
- DACH1 | c.1273C>T p.L425= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- DACT1 | c.1027C>T p.L343= | Silent (SNP) | VAF 14/183 reads (8%) | called by muse, mutect2
- IKZF2 | c.195G>A p.L65= | Silent (SNP) | VAF 21/208 reads (10%) | called by muse, mutect2, varscan2
- KMT2E | c.4617G>A p.L1539= | Silent (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- PATJ | c.2950C>T p.L984= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as rs1435252387; called by muse, mutect2
- FBXW7 | c.502-2560A>T | Intron (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
